CPTAC case C3N-00498 — Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad5ce87b-dd1f-418e-9540-c79505417ece

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 63.3 years (23,112 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,704 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,704 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 12; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 254 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 625 days (1.7 years); Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 1,180 days (3.2 years); Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 1,421 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 1,704 days (4.7 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 1,704 days (4.7 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV16].

Other clinical attributes
- Weight: 84 kg; Height: 176 cm; BMI: 27.12.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00498-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.181 mg.
- Sample C3N-00498-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 78 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00498-22: Section location: Oral Cavity; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-00498-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.389 mg.
- Sample C3N-00498-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 177 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00498-24: Section location: Oral Cavity; Percent tumor nuclei: 95; Percent necrosis: 15.
- Sample C3N-00498-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 100 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00498-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
